Somatic mutation profile of cancer-model specimen HCM-CSHL-0371-C25-85A (3D Organoid; aliquot HCM-CSHL-0371-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0371-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 75.0 years (27,380 days).
Specimen HCM-CSHL-0371-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6339f1c2-1310-4f6c-afdd-454ffe5c94e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0371-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0371-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1980ea44-d162-4399-a3ad-561f56d9e687

The open-access MAF lists 140 somatic variants for this specimen: 81 protein-altering or splice-affecting, 44 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 44, Nonsense Mutation 8, Intron 7, 5'Flank 5, Splice Region 4, RNA 1, 5'UTR 1, 3'UTR 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 178/178 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APP | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.328); catalogued as rs559207950; called by muse, mutect2, varscan2
- C11orf87 | c.98C>G p.T33R | Missense Mutation (SNP) | VAF 65/469 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs770432187, COSV59356798, COSV99046614; called by muse, mutect2, varscan2
- C19orf44 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.146); catalogued as rs148603243; called by muse, mutect2, varscan2
- C2orf81 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1295792940; called by muse, mutect2, varscan2
- CABIN1 | c.5288C>T p.T1763M | Missense Mutation (SNP) | VAF 287/600 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.323); catalogued as rs777805735; called by muse, mutect2, varscan2
- CAST | c.433G>T p.D145Y (on ENST00000341926; = p.D228Y on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100352068; called by muse, mutect2, varscan2
- CBLC | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.555); catalogued as COSV54322029; called by muse, mutect2, varscan2
- CDH19 | c.2069C>A p.P690H | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50966588; called by muse, mutect2, varscan2
- CLCN5 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 233/233 reads (100%) | catalogued as CM157765; called by muse, mutect2, varscan2
- COL2A1 | c.2848G>T p.A950S | Missense Mutation (SNP) | VAF 344/345 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs762151026; called by muse, mutect2, varscan2
- COL4A6 | c.316A>G p.N106D | Missense Mutation (SNP) | VAF 91/91 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1556025042; called by muse, mutect2, varscan2
- DLG2 | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 140/285 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs770732545; called by muse, mutect2, varscan2
- DNAH11 | c.12753T>A p.V4251= | Splice Region (SNP) | VAF 48/96 reads (50%) | catalogued as COSV60985810; called by muse, mutect2, varscan2
- EIF3B | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.197); catalogued as rs1272815595; called by muse, mutect2, varscan2
- EMP3 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs749117341, COSV99507629; called by muse, mutect2, varscan2
- ESRRB | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 205/438 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as rs752511322, COSV55060080; called by muse, mutect2, varscan2
- FAM3B | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 257/258 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs970237251, COSV63613053; called by muse, mutect2, varscan2
- GABRB1 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 132/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs999920078, COSV54973905, COSV54977638; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 222/566 reads (39%) | catalogued as rs774107858; called by muse, varscan2
- GPN2 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs1344789220; called by muse, mutect2, varscan2
- GPN2 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV64652058; called by muse, mutect2, varscan2
- GRM7 | c.2594C>T p.A865V | Missense Mutation (SNP) | VAF 187/410 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs55716077; called by muse, mutect2, varscan2
- IRF2BPL | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.936); catalogued as COSV53148925; called by muse, mutect2, varscan2
- KIF1A | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372544960; called by muse, mutect2, varscan2
- LHX8 | c.18+4A>G | Splice Region (SNP) | VAF 90/489 reads (18%) | catalogued as COSV53958491, COSV53960721; called by muse, mutect2, varscan2
- MNX1 | c.1074G>C p.E358D | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV53317600, COSV99429687; called by muse, mutect2, varscan2
- MYBPC2 | c.3172G>T p.V1058L | Missense Mutation (SNP) | VAF 114/238 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.239); catalogued as COSV63097282; called by muse, mutect2, varscan2
- PCDHA7 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.072); catalogued as COSV65343873; called by muse, varscan2
- PRKG1 | c.1825C>A p.L609I | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64770865, COSV64776061; called by muse, mutect2
- RALGAPB | c.3790G>T p.V1264L | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs775402377; called by muse, mutect2, varscan2
- SCUBE1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT tolerated, low confidence (0.71); PolyPhen possibly damaging (0.449); catalogued as rs1228359802; called by muse, mutect2, varscan2
- SLITRK5 | c.2234C>G p.A745G | Missense Mutation (SNP) | VAF 72/72 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV61520933; called by muse, mutect2, varscan2
- TTC16 | c.2335C>A p.R779S | Missense Mutation (SNP) | VAF 225/444 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV60160667; called by muse, mutect2, varscan2
- TYR | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 221/429 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1284073098, CM100989, COSV54484761; called by muse, mutect2, varscan2
- UBXN11 | c.218C>T p.S73L (on ENST00000374221 / NM_183008.2; = p.S40L on NM_145345.2) | Missense Mutation (SNP) | VAF 149/330 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs766490537; called by muse, mutect2, varscan2
- XRRA1 | c.2051_2053del p.K684del | In Frame Del (DEL) | VAF 58/146 reads (40%) | catalogued as rs746909441; called by pindel, varscan2
- ABCC4 | c.1788C>A p.Y596* | Nonsense Mutation (SNP) | VAF 66/66 reads (100%) | called by muse, mutect2, varscan2
- ACVR1B | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 309/309 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM23 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRG1 | c.1510G>C p.V504L | Missense Mutation (SNP) | VAF 199/399 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- ALS2 | c.2368A>G p.T790A | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APBA2 | c.1415G>T p.R472I | Missense Mutation (SNP) | VAF 98/434 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1E | c.1498C>A p.Q500K | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2
- COL11A1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- COL5A2 | c.3046C>G p.P1016A | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- DLGAP5 | c.2163T>G p.S721R | Missense Mutation (SNP) | VAF 103/205 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- DNAH3 | c.2410C>A p.L804M | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- EIF4G1 | c.3112C>T p.P1038S (on ENST00000346169 / NM_198241.3; = p.P843S on NM_004953.5) | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- EMCN | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- EP300 | c.5583A>C p.Q1861H | Missense Mutation (SNP) | VAF 89/168 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- EPHA6 | c.2706C>A p.S902R (on ENST00000389672 / NM_001080448.3; = p.S294R on NM_173655.4) | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- EVC | c.2572C>A p.Q858K | Missense Mutation (SNP) | VAF 222/482 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, varscan2
- FREM3 | c.3260C>A p.S1087Y | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- GNGT2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- HK3 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 270/570 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HS3ST4 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- IL4R | c.811del p.R271Afs*7 | Frame Shift Del (DEL) | VAF 143/375 reads (38%) | called by mutect2, pindel, varscan2
- IPO4 | c.237-7G>C | Splice Region (SNP) | VAF 90/389 reads (23%) | called by muse, mutect2, varscan2
- IRAK2 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- KIAA0586 | c.448G>A p.E150K (on ENST00000619416 / NM_001244190.2; = p.E165K on NM_014749.5) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2
- KIAA1109 | c.8052G>T p.M2684I | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- KIAA1109 | c.8053G>T p.D2685Y | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA1210 | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2
- MAST2 | c.1870G>T p.E624* | Nonsense Mutation (SNP) | VAF 112/277 reads (40%) | called by muse, mutect2, varscan2
- NPAS3 | c.307A>T p.M103L (on ENST00000356141 / NM_001164749.2; = p.M73L on NM_022123.3) | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NUP214 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIEZO2 | c.5690C>A p.S1897* | Nonsense Mutation (SNP) | VAF 42/188 reads (22%) | called by muse, mutect2, varscan2
- PLCH2 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 199/406 reads (49%) | called by muse, mutect2, varscan2
- POU3F3 | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 68/510 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO3A1 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 197/410 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLCO5A1 | c.2291A>C p.E764A | Missense Mutation (SNP) | VAF 242/543 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SPDYA | c.734C>G p.S245* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- TEX52 | c.277T>A p.W93R | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- TMEM86B | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13C | c.5686T>G p.L1896V | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDFY3 | c.1587A>T p.E529D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, varscan2
- ZC3H4 | c.2794C>G p.L932V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF23 | c.391T>C p.C131R | Missense Mutation (SNP) | VAF 130/254 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF610 | c.-18A>T | Splice Region (SNP) | VAF 52/106 reads (49%) | called by muse, mutect2, varscan2
- ZNF99 | c.1466C>A p.A489D | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.3138C>T p.S1046= | Silent (SNP) | VAF 106/229 reads (46%) | called by muse, mutect2, varscan2
- ACTC1 | c.1042C>T p.L348= | Silent (SNP) | VAF 175/358 reads (49%) | catalogued as COSV51761529; called by muse, mutect2, varscan2
- ADCY7 | c.345A>G p.A115= | Silent (SNP) | VAF 33/188 reads (18%) | catalogued as rs370202574; called by muse, mutect2, varscan2
- ADNP | c.2154T>G p.T718= | Silent (SNP) | VAF 117/290 reads (40%) | called by muse, mutect2, varscan2
- BCL11B | c.1734C>T p.G578= (on ENST00000357195 / NM_001282237.2; = p.G507= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 229/481 reads (48%) | called by muse, mutect2, varscan2
- CACNA1D | c.3027C>T p.F1009= (on ENST00000350061 / NM_001128840.3; = p.F1029= on NM_000720.4) | Silent (SNP) | VAF 26/241 reads (11%) | catalogued as rs756714892; called by muse, mutect2, varscan2
- CAST | c.432G>T p.P144= (on ENST00000341926; = p.P227= on NM_001750.7 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs373067588; called by muse, mutect2, varscan2
- CBARP | c.1401T>C p.H467= | Silent (SNP) | VAF 153/364 reads (42%) | catalogued as rs746669456; called by muse, mutect2, varscan2
- CDH23 | c.7716G>A p.Q2572= | Silent (SNP) | VAF 184/404 reads (46%) | called by muse, mutect2, varscan2
- CFAP46 | c.3117C>T p.N1039= | Silent (SNP) | VAF 225/413 reads (54%) | catalogued as rs754188508, COSV100886827, COSV63951484; called by muse, mutect2, varscan2
- CTXN1 | c.207G>A p.K69= | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- CYP17A1 | c.1158G>T p.V386= | Silent (SNP) | VAF 309/596 reads (52%) | called by muse, mutect2, varscan2
- CYP2D7 | c.693G>T p.P231= | Silent (SNP) | VAF 264/479 reads (55%) | called by muse, mutect2, varscan2
- EIF1B | c.312G>A p.K104= | Silent (SNP) | VAF 74/179 reads (41%) | called by muse, mutect2, varscan2
- ESR1 | c.1197A>G p.P399= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as rs778077270; called by muse, mutect2, varscan2
- EVC | c.2571C>A p.S857= | Silent (SNP) | VAF 219/476 reads (46%) | called by muse, varscan2
- FMN1 | c.2523C>G p.L841= (on ENST00000616417 / NM_001277313.2; = p.L618= on NM_001103184.4) | Silent (SNP) | VAF 78/182 reads (43%) | called by muse, mutect2, varscan2
- FREM3 | c.3261C>A p.S1087= | Silent (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- GFRA4 | c.549C>A p.R183= (on ENST00000319242 / NM_145762.3; = p.A157D on NM_022139.4) | Silent (SNP) | VAF 39/40 reads (98%) | called by muse, mutect2, varscan2
- GOLGA6L22 | c.1389G>T p.R463= | Silent (SNP) | VAF 214/568 reads (38%) | called by muse, varscan2
- HELZ2 | c.3738G>A p.R1246= (on ENST00000467148 / NM_001037335.2; = p.R677= on NM_033405.3) | Silent (SNP) | VAF 114/238 reads (48%) | catalogued as rs1569033051; called by muse, mutect2, varscan2
- KLK14 | c.204C>T p.C68= | Silent (SNP) | VAF 48/93 reads (52%) | catalogued as rs369907925; called by muse, mutect2, varscan2
- MAN1A1 | c.1057C>T p.L353= | Silent (SNP) | VAF 85/86 reads (99%) | called by muse, mutect2, varscan2
- MAST2 | c.1869G>C p.L623= | Silent (SNP) | VAF 115/279 reads (41%) | called by muse, mutect2, varscan2
- MEX3A | c.840G>A p.A280= | Silent (SNP) | VAF 113/540 reads (21%) | catalogued as rs368560209; called by muse, mutect2, varscan2
- MYH4 | c.72A>T p.R24= | Silent (SNP) | VAF 47/224 reads (21%) | called by muse, mutect2, varscan2
- MYRFL | c.1857G>A p.A619= | Silent (SNP) | VAF 123/123 reads (100%) | catalogued as rs1229991582; called by muse, mutect2, varscan2
- NAALAD2 | c.1626C>T p.Y542= | Silent (SNP) | VAF 80/148 reads (54%) | called by mutect2, varscan2
- NLRP6 | c.156G>A p.P52= | Silent (SNP) | VAF 61/107 reads (57%) | catalogued as rs1035005411; called by muse, mutect2, varscan2
- NRXN2 | c.273C>T p.F91= | Silent (SNP) | VAF 55/365 reads (15%) | called by muse, mutect2, varscan2
- OTUD7A | c.1995G>A p.L665= (on ENST00000307050 / NM_001382637.1; = p.L658= on NM_130901.3) | Silent (SNP) | VAF 27/283 reads (10%) | catalogued as COSV61040108; called by muse, mutect2
- PCYT1B | c.399C>T p.Y133= | Silent (SNP) | VAF 90/90 reads (100%) | catalogued as rs753540289; called by muse, mutect2, varscan2
- PRDM8 | c.1617C>T p.P539= | Silent (SNP) | VAF 268/539 reads (50%) | called by muse, mutect2, varscan2
- PRKG1 | c.1827A>T p.L609= | Silent (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2
- RBPMS2 | c.540T>A p.T180= | Silent (SNP) | VAF 140/332 reads (42%) | called by muse, mutect2, varscan2
- RLIM | c.1218A>G p.L406= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as rs1293873232; called by muse, mutect2, varscan2
- SALL2 | c.2658C>T p.T886= | Silent (SNP) | VAF 139/265 reads (52%) | called by muse, mutect2, varscan2
- SALL4 | c.1101C>A p.S367= | Silent (SNP) | VAF 125/273 reads (46%) | catalogued as COSV53850134; called by muse, mutect2, varscan2
- SHANK1 | c.2586C>T p.F862= | Silent (SNP) | VAF 102/213 reads (48%) | catalogued as rs1216154072, COSV53243998; called by muse, mutect2, varscan2
- STS | c.963G>T p.L321= | Silent (SNP) | VAF 175/175 reads (100%) | called by muse, mutect2, varscan2
- TCOF1 | c.513A>C p.S171= | Silent (SNP) | VAF 289/587 reads (49%) | called by muse, mutect2, varscan2
- TIGIT | c.291G>A p.S97= | Silent (SNP) | VAF 136/287 reads (47%) | catalogued as rs762180739; called by muse, mutect2, varscan2
- TMEM132A | c.1977G>A p.G659= (on ENST00000453848 / NM_178031.3; = p.G660= on NM_017870.4) | Silent (SNP) | VAF 8/234 reads (3%) | called by muse, mutect2
- TMEM86B | c.558G>T p.L186= | Silent (SNP) | VAF 34/98 reads (35%) | called by muse, mutect2, varscan2
- AL162417.1 | c.397-17044C>A | Intron (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- AP000769.3 | chr11:65504234 ins TATCAGC | 5'Flank (INS) | VAF 39/119 reads (33%) | called by mutect2, varscan2
- ARVCF | c.210+3475C>T | Intron (SNP) | VAF 13/58 reads (22%) | catalogued as rs775266970; called by muse, mutect2
- FAM53C | chr5:138338125 G>C | 5'Flank (SNP) | VAF 99/213 reads (46%) | called by muse, mutect2, varscan2
- HSPA7 | n.570G>T | RNA (SNP) | VAF 160/626 reads (26%) | called by muse, mutect2, varscan2
- LDLR | c.2390-41C>T | Intron (SNP) | VAF 98/214 reads (46%) | called by muse, varscan2
- NOD2 | c.3050+10C>T | Intron (SNP) | VAF 183/400 reads (46%) | called by muse, mutect2, varscan2
- PRICKLE3 | c.426+12G>C | Intron (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
- RABEPK | c.-297C>T | 5'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159469 G>A | 5'Flank (SNP) | VAF 24/50 reads (48%) | catalogued as rs79877727; called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81108590 G>A | 5'Flank (SNP) | VAF 84/206 reads (41%) | called by muse, mutect2, varscan2
- RPS27L | c.226+38T>A | Intron (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2
- TH | c.*9C>T | 3'UTR (SNP) | VAF 7/13 reads (54%) | catalogued as rs762091461; called by muse, mutect2, varscan2
- UNC13A | chr19:17688246 C>T | 5'Flank (SNP) | VAF 18/39 reads (46%) | catalogued as rs1296546997; called by muse, mutect2, varscan2
- USP46 | c.999+12G>T | Intron (SNP) | VAF 87/204 reads (43%) | called by muse, mutect2, varscan2
